Somatic mutation profile of tumor specimen TCGA-HU-A4G2-01A (aliquot TCGA-HU-A4G2-01A-11D-A25D-08) from TCGA case TCGA-HU-A4G2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.0 years (16,791 days).
Specimen TCGA-HU-A4G2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d59f7bfd-23ae-483f-8c31-febb5fb745a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4G2-10A (Blood Derived Normal), aliquot TCGA-HU-A4G2-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fde63801-a1c5-47d2-b85c-18f8158b82c7

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 26, Silent 14, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as rs769751827, COSV55116258; called by muse, mutect2, varscan2
- B3GAT3 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53881360; called by muse, mutect2
- CDH19 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs751067735, COSV50954344; called by muse, mutect2, varscan2
- CHRNA4 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as rs76895198, COSV64718380; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.898-1G>T p.X300_splice | Splice Site (SNP) | VAF 38/186 reads (20%) | catalogued as CS1412446, COSV58581857; called by muse, mutect2, varscan2
- COL5A3 | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 83/229 reads (36%) | catalogued as COSV53406077; called by muse, varscan2
- CPT2 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53758655; called by muse, mutect2
- CUX1 | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782786732, COSV99470850; called by muse, mutect2
- DALRD3 | c.1064-1G>A p.X355_splice (on ENST00000341949 / NM_001009996.3; = p.X188_splice on NM_018114.5) | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV58243908, COSV58244878; called by muse, mutect2, varscan2
- DLL3 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1235864005, COSV52693257; called by muse, mutect2, varscan2
- DPYD | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.911); catalogued as COSV64590592; called by muse, mutect2, varscan2
- FBN2 | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs367787287, COSV99326483; called by muse, mutect2, varscan2
- FBXL7 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs1389047293, COSV61641082, COSV61645644; called by muse, mutect2, varscan2
- GALNTL6 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101487779, COSV71826060; called by muse, mutect2, varscan2
- IGF2 | c.367G>A p.V123I (on ENST00000434045 / NM_001127598.3; = p.V67I on NM_000612.6) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs1564894953, COSV56097061; called by muse, mutect2, varscan2
- KLC1 | c.1321A>G p.K441E | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV55805620; called by muse, mutect2, varscan2
- MDGA2 | c.2132C>A p.P711Q (on ENST00000399232 / NM_001113498.2; = p.P413Q on NM_182830.4) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV62079033; called by muse, mutect2, varscan2
- MUC16 | c.5770A>G p.T1924A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67444244; called by muse, mutect2, varscan2
- NFASC | c.2461G>A p.G821R (on ENST00000339876 / NM_001378329.1; = p.G817R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58358603; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- RHO | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56212367, COSV56213204; called by muse, mutect2, varscan2
- RNF175 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs755603150, COSV56840497; called by muse, mutect2, varscan2
- RTN4IP1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV64804894; called by muse, mutect2
- SCN5A | c.4913G>A p.R1638Q (on ENST00000333535 / NM_198056.3; = p.R1637Q on NM_000335.5) | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs374557801, COSV61123571; called by muse, mutect2, varscan2
- SMAD4 | c.1148T>G p.I383R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM100520, COSV61684469, COSV61697721; called by muse, mutect2, varscan2
- SPART | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375284717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK31 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs1369485527, COSV100669286, COSV63453958; called by muse, mutect2, varscan2
- UGT1A1 | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV59381593; called by muse, mutect2
- UNC13A | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1377403332, COSV53188175; called by muse, mutect2, varscan2
- VPS13C | c.8590C>T p.R2864* (on ENST00000644861 / NM_020821.3; = p.R2821* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as rs751495707, COSV51121344; called by muse, mutect2, varscan2
- VWC2 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV61482407, COSV61483233; called by muse, mutect2, varscan2
- WWC2 | c.1385A>G p.N462S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs758105845, COSV66712312; called by muse, mutect2, varscan2
- ZNF425 | c.1999C>A p.Q667K | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV65200545; called by muse, mutect2, varscan2
- MUC6 | c.3976del p.R1326Gfs*4 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | called by mutect2, pindel, varscan2
- PARP16 | c.364_375delinsAGGAC p.P122Rfs*24 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by pindel, varscan2*
- TCF12 | c.1274dup p.L425Ffs*7 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- ADGRE3 | c.1317G>A p.L439= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV53728322; called by muse, mutect2, varscan2
- CEP131 | c.2133G>A p.L711= (on ENST00000269392 / NM_001319228.2; = p.L708= on NM_014984.4) | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1187580595, COSV99487962; called by mutect2, varscan2
- CFAP54 | c.6069G>A p.A2023= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs759002580, COSV61570495; called by muse, mutect2, varscan2
- GPR45 | c.48G>A p.L16= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs763631663, COSV51522696; called by muse, mutect2, varscan2
- IL17RA | c.1332C>T p.I444= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs1462547837, COSV60051216; called by muse, mutect2, varscan2
- IRF8 | c.570G>A p.T190= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs757320154, COSV51896645; called by muse, mutect2, varscan2
- KLHL18 | c.1005C>T p.N335= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs769163927, COSV51743945; called by muse, mutect2, varscan2
- NLRP7 | c.558G>A p.T186= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as COSV60170941; called by muse, mutect2, varscan2
- PNPT1 | c.558A>G p.G186= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV53175650; called by muse, mutect2, varscan2
- SERPINA9 | c.69G>A p.P23= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs746305930, COSV54072743; called by muse, mutect2, varscan2
- SMYD4 | c.1749C>T p.A583= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs140685899; called by muse, mutect2, varscan2
- VENTX | c.324C>T p.G108= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs560345091, COSV58084031; called by muse, mutect2, varscan2
- ZFP69 | c.144T>C p.D48= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV65528314; called by muse, mutect2, varscan2
- ZNF667 | c.1047G>A p.Q349= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV52631084; called by muse, mutect2
